Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5703, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5703-01A (Primary Tumor).

PRE-OP DIAGNOSIS: Left kidney cancer
POST-OP DIAGNOSIS: Same.
PROCEDURE: Laparoscopic left nephrectomy.

FINAL DIAGNOSIS:

KIDNEY, LEFT, LAPAROSCOPIC LEFT NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 3.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 5.5 cm.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- I. TNM STAGE: pT1b NX MX.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Other: Laparoscopic nephrectomy

LATERALITY: Left

TUMOR SITE: Lower pole

FOCALITY: Unifocal

TUMOR SIZE: Greatest dimension: 5.5 cm

Additional dimensions: 5.3 x 4.5 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G3

PATHOLOGIC STAGING (pTNM): pT1b

pNX

Number of regional lymph nodes examined: 0

pMX

MARGINS: Margins uninvolved by invasive carcinoma

ADRENAL GLAND: Not present

VENOUS (LARGE VESSEL) INVASION (V): Absent

LYMPHATIC (SMALL VESSEL) INVASION (L): Absent

Source: NCI Genomic Data Commons file 1f3c2635-1e0a-44f5-aa3a-d67dd3d442f2 (TCGA-B0-5703.8695872F-42DB-44B9-A326-464BC1D0F411.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).